Gene-level copy-number profile of tumor specimen HCM-BROD-0472-C34-06B from HCMI case HCM-BROD-0472-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.9 years (24,082 days).
Specimen HCM-BROD-0472-C34-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7615c35-3d02-4b3e-a096-34a58a913fb4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0472-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/801de303-914f-496a-9792-4c5f761d1e1c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 1,372; copy number 2: 19,529; copy number 3: 18,279; copy number 4: 11,439; copy number 5: 4,700; copy number 6: 2,276; copy number 7: 761; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes (within-gene range 0–5): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr19:10,960,932–11,079,426, 4 genes: SMARCA4, AC011442.1, RN7SL192P, AC006127.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 766 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–95,172,377, 15 genes, copy number 7: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6.
- chr6:20,212,087–21,602,383, 17 genes, copy number 7 (within-gene range 3–7): AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr16:35,021,749–35,085,060, 5 genes, copy number 12 (within-gene range 2–12): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr19:7,492,976–7,561,764, 7 genes, copy number 7 (within-gene range 3–7): TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6.
- chr21:13,038,160–46,691,226, 722 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
